Somatic mutation profile of tumor specimen C3N-01022-02 (aliquot CPT0117790009) from CPTAC case C3N-01022, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 55.3 years (20,195 days).
Specimen C3N-01022-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10f40a65-0ab3-452c-8fe2-faabd48c9c4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01022-31 (Blood Derived Normal), aliquot CPT0119030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7007c886-d60d-4954-b7e3-d3716985259c

The open-access MAF lists 737 somatic variants for this specimen: 516 protein-altering or splice-affecting, 132 silent, 89 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 442, Silent 132, Intron 42, Nonsense Mutation 34, Splice Site 20, RNA 14, 3'UTR 12, Frame Shift Del 12, 5'Flank 10, 5'UTR 7, Splice Region 5, 3'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 53/383 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.560-1G>T p.X187_splice | Splice Site (SNP) | VAF 84/441 reads (19%) | hotspot (GDC flag); catalogued as CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; called by muse, mutect2, varscan2
- A1CF | c.1166G>A p.G389E (on ENST00000373993 / NM_138932.2; = p.G381E on NM_014576.4) | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV51030119; called by muse, mutect2, varscan2
- AC013477.1 | c.2492G>T p.R831M | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs553628892, COSV99549139; called by muse, mutect2, varscan2
- ACAN | c.4203G>C p.E1401D | Missense Mutation (SNP) | VAF 102/739 reads (14%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.952); catalogued as COSV61361025; called by muse, varscan2
- ACP7 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs746887864; called by muse, mutect2
- ADAM18 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.453); catalogued as rs374893239; called by muse, mutect2, varscan2
- ADAMTS2 | c.1059C>A p.D353E | Missense Mutation (SNP) | VAF 55/411 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.532); catalogued as rs1210785791; called by muse, mutect2, varscan2
- ADGRF2 | c.833T>C p.I278T (on ENST00000296862 / NM_001368115.2; = p.I210T on NM_153839.7) | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as rs757632775, COSV57288503; called by muse, mutect2, varscan2
- AGBL1 | c.2314C>G p.P772A | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66854162; called by muse, mutect2, varscan2
- AKR1D1 | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 24/183 reads (13%) | catalogued as COSV54336356, COSV99653298; called by muse, mutect2, varscan2
- AR | c.1600C>A p.P534T | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.281); catalogued as COSV65953145; called by muse, mutect2, varscan2
- ARHGEF2 | c.2198C>A p.S733* (on ENST00000361247 / NM_001162383.2; = p.S705* on NM_004723.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/358 reads (8%) | catalogued as COSV58113742; called by muse, mutect2
- ASH1L | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 102/403 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV64210118; called by muse, mutect2, varscan2
- ASPM | c.9526G>T p.E3176* | Nonsense Mutation (SNP) | VAF 52/408 reads (13%) | catalogued as COSV54128692, COSV54137736; called by muse, mutect2, varscan2
- ATP8B2 | c.2344G>T p.V782F (on ENST00000672630; = p.V749F on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.722); catalogued as COSV59248695; called by muse, mutect2, varscan2
- B4GALT4 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.111); catalogued as COSV63295472; called by muse, mutect2, varscan2
- BCL11B | c.2093C>A p.P698H (on ENST00000357195 / NM_001282237.2; = p.P627H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as rs1489021963; called by muse, varscan2
- BNIP2 | c.-57G>A | Splice Region (SNP) | VAF 27/99 reads (27%) | catalogued as rs550464185; called by muse, mutect2, varscan2
- C17orf80 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 54/331 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.677); catalogued as rs764706565; called by muse, mutect2, varscan2
- CACNA1I | c.5266C>A p.H1756N | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV60801836; called by muse, mutect2
- CADM1 | c.1329G>T p.*443Yext*15 | Nonstop Mutation (SNP) | VAF 68/378 reads (18%) | catalogued as COSV59012750; called by mutect2, varscan2
- CAMK2B | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.421); catalogued as rs537194603; called by muse, mutect2, varscan2
- CBR3 | c.155C>A p.A52E | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as rs761325372; called by muse, mutect2
- CCDC148 | c.1370+1G>C p.X457_splice | Splice Site (SNP) | VAF 20/269 reads (7%) | catalogued as rs772262143; called by muse, mutect2
- CCR6 | c.128A>C p.Q43P | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as rs770674712; called by muse, mutect2, varscan2
- CHEK1 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54024171; called by muse, mutect2, varscan2
- CLCN1 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 94/627 reads (15%) | catalogued as CM139458; called by muse, mutect2, varscan2
- COL4A5 | c.2731G>T p.G911* | Nonsense Mutation (SNP) | VAF 75/233 reads (32%) | catalogued as COSV60373840; called by muse, mutect2, varscan2
- COL8A2 | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs904607082; called by muse, mutect2, varscan2
- CRB1 | c.2339C>A p.P780H | Missense Mutation (SNP) | VAF 66/362 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as rs1481310279, COSV66330378; called by muse, mutect2, varscan2
- DMD | c.5443G>T p.D1815Y | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759794196, COSV63759156; called by muse, mutect2, varscan2
- DMXL1 | c.7059G>T p.E2353D | Missense Mutation (SNP) | VAF 44/371 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60708305; called by muse, mutect2, varscan2
- EDN3 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100285094, COSV100285140; called by muse, mutect2
- EPB41L2 | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61353484; called by muse, mutect2, varscan2
- ESPNL | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.913); catalogued as rs1394690658; called by mutect2, varscan2
- F2RL2 | c.177G>T p.W59C | Missense Mutation (SNP) | VAF 58/389 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as rs745784256; called by muse, mutect2, varscan2
- F5 | c.5069C>A p.S1690Y | Missense Mutation (SNP) | VAF 37/540 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63122701; called by muse, mutect2
- F5 | c.4649A>G p.Y1550C | Missense Mutation (SNP) | VAF 32/538 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1276506221; called by muse, mutect2
- FAT3 | c.6820G>T p.D2274Y | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53187484; called by muse, mutect2, varscan2
- FGA | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 62/391 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs1332993638; called by muse, varscan2
- FGF12 | c.469G>T p.V157L (on ENST00000454309 / NM_021032.5; = p.V95L on NM_004113.6) | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as COSV53160980; called by muse, mutect2, varscan2
- FKBP15 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53033405; called by muse, mutect2, varscan2
- FLNC | c.6006G>C p.G2002= | Splice Region (SNP) | VAF 36/276 reads (13%) | catalogued as rs949178854; called by muse, mutect2, varscan2
- FTCD | c.1106C>G p.A369G | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as rs754562126; called by muse, mutect2
- GIPC2 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs762485885; called by muse, mutect2, varscan2
- GRIN3A | c.647T>A p.L216Q | Missense Mutation (SNP) | VAF 93/317 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV62456359; called by muse, mutect2, varscan2
- GZMH | c.107C>G p.A36G | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53539423; called by muse, mutect2, varscan2
- HABP2 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.054); catalogued as rs374555726; called by muse, mutect2, varscan2
- HELZ | c.4316G>A p.R1439Q | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs947435256; called by muse, mutect2
- HJV | c.520del p.H174Mfs*72 (on ENST00000336751 / NM_213653.4; = p.H61Mfs*72 on NM_145277.5) | Frame Shift Del (DEL) | VAF 126/617 reads (20%) | catalogued as rs782782722; called by mutect2, varscan2
- HNRNPCL2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs746366523; called by muse, mutect2, varscan2
- IFIT2 | c.995A>C p.N332T | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as rs1564781958; called by muse, mutect2, varscan2
- IFT172 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV53141761; called by muse, mutect2, varscan2
- IMMP2L | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.626); catalogued as rs200230478; called by muse, mutect2, varscan2
- INVS | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 42/464 reads (9%) | catalogued as COSV99317110; called by muse, mutect2
- IRF5 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs368255860; called by muse, mutect2, varscan2
- ITIH4 | c.2596C>T p.R866C | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs368376301; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD16 | c.1149A>C p.K383N | Missense Mutation (SNP) | VAF 85/422 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV72576444; called by muse, varscan2
- KEL | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 42/334 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs371571715; called by muse, mutect2, varscan2
- KHSRP | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs1197165582; called by muse, mutect2, varscan2
- KIF26A | c.2620G>T p.G874W | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs765433876; called by muse, mutect2, varscan2
- KIF4B | c.3187G>T p.D1063Y | Missense Mutation (SNP) | VAF 86/547 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV70530074; called by muse, mutect2, varscan2
- KRTAP13-1 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100819885; called by muse, mutect2, varscan2
- LCE3E | c.200G>T p.R67M | Missense Mutation (SNP) | VAF 27/382 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.192); catalogued as COSV64231576; called by muse, mutect2
- LHCGR | c.2066C>A p.A689D | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs752989860, COSV54294483; called by muse, varscan2
- LRP1B | c.3998G>T p.G1333V | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67184577; called by muse, mutect2, varscan2
- LRP1B | c.3190G>T p.G1064C | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67199567, COSV67247877; called by muse, mutect2, varscan2
- MAPK14 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 6/130 reads (5%) | catalogued as rs1173776676, COSV100004830; called by muse, mutect2
- MEGF8 | c.8470G>A p.G2824R (on ENST00000251268 / NM_001271938.2; = p.G2757R on NM_001410.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.727); catalogued as rs1437325934; called by mutect2, varscan2
- METTL21C | c.686C>A p.T229N | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV57433377; called by muse, mutect2, varscan2
- MPP3 | c.1275G>T p.K425N | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV101263370, COSV68197472; called by muse, mutect2, varscan2
- MUC16 | c.28361G>A p.G9454E | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.028); catalogued as rs776994195; called by muse, mutect2, varscan2
- MUC16 | c.21955G>T p.A7319S | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); catalogued as COSV67464207; called by muse, mutect2
- MUC16 | c.9896G>C p.G3299A | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.925); catalogued as COSV67491477, COSV67493371; called by muse, mutect2
- MUC17 | c.12464G>A p.G4155E | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs150974700; called by muse, mutect2, varscan2
- MYO9A | c.3806G>T p.R1269L | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61854668; called by muse, mutect2, varscan2
- NBAS | c.6144G>T p.L2048F | Missense Mutation (SNP) | VAF 38/351 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55740414; called by muse, mutect2, varscan2
- NBEAL2 | c.7856C>T p.A2619V | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs754216869, COSV52754106; called by muse, mutect2
- NCOA1 | c.2114T>C p.L705S | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1486708920; called by muse, mutect2, varscan2
- NCOA3 | c.4057G>T p.A1353S (on ENST00000371998 / NM_181659.3; = p.A1349S on NM_006534.4) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59070951; called by muse, mutect2, varscan2
- NCOA6 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 13/247 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV62865434, COSV62868941; called by muse, mutect2
- NGEF | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772128910, COSV50964617; called by muse, mutect2, varscan2
- NOC4L | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as rs576894396; called by muse, varscan2
- NOTCH2 | c.5111G>A p.R1704H | Missense Mutation (SNP) | VAF 62/507 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.139); catalogued as rs764895571, CM137595; called by muse, mutect2, varscan2
- NPR1 | c.101A>G p.N34S | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.242); catalogued as rs1174456586; called by muse, mutect2, varscan2
- NR1D2 | c.295A>T p.M99L | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.09); catalogued as rs776378040; called by muse, mutect2, varscan2
- OR10J1 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 54/411 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71128653; called by muse, varscan2
- OR10T2 | c.725C>A p.A242D | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57781354; called by muse, mutect2
- OR2AK2 | c.158C>A p.T53N | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV100823161; called by muse, mutect2, varscan2
- OR51T1 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV59025805; called by muse, mutect2, varscan2
- OR52M1 | c.833T>C p.L278P | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778043020; called by muse, mutect2, varscan2
- OR52N2 | c.554C>A p.S185Y | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57677540; called by muse, mutect2, varscan2
- OR5AS1 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs1291549525, COSV100546161; called by muse, mutect2, varscan2
- OR5B2 | c.378del p.K126Nfs*9 | Frame Shift Del (DEL) | VAF 29/150 reads (19%) | catalogued as rs1406118484; called by mutect2, pindel, varscan2
- OR5B3 | c.208del p.C70Afs*16 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | catalogued as COSV58677481; called by pindel, varscan2
- OR5H6 | c.51G>T p.M17I (on ENST00000642105; = p.M1? on NM_001005479.2) | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV67351265; called by muse, mutect2, varscan2
- OR5H6 | c.52G>T p.E18* (on ENST00000642105; = p.E2* on NM_001005479.2) | Nonsense Mutation (SNP) | VAF 25/155 reads (16%) | catalogued as COSV67351186; called by muse, mutect2, varscan2
- OR5M10 | c.846C>G p.S282R | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1437837289; called by muse, mutect2, varscan2
- OR6K6 | c.305C>A p.T102N (on ENST00000368144; = p.T78N on NM_001005184.1) | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs1344601790; called by muse, mutect2
- OXTR | c.922+1G>T p.X308_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as rs768108062; called by muse, mutect2, varscan2
- P3H3 | c.1040C>A p.P347Q | Missense Mutation (SNP) | VAF 46/380 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51834045; called by muse, mutect2, varscan2
- PADI1 | c.629G>C p.R210T | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1330881996, COSV64938251; called by muse, mutect2, varscan2
- PAPLN | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99059763; called by muse, mutect2, varscan2
- PCDH9 | c.2649C>A p.N883K | Missense Mutation (SNP) | VAF 57/314 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.836); catalogued as rs371380403; called by muse, mutect2, varscan2
- PCDHA3 | c.2377G>A p.V793I | Missense Mutation (SNP) | VAF 50/313 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs1306203317, COSV63543040; called by muse, mutect2, varscan2
- PDZRN3 | c.1860C>A p.F620L | Missense Mutation (SNP) | VAF 78/439 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.628); catalogued as COSV99732551; called by muse, mutect2, varscan2
- PGBD2 | c.677C>G p.S226* | Nonsense Mutation (SNP) | VAF 39/457 reads (9%) | catalogued as COSV61401171; called by muse, mutect2
- PIP5K1A | c.374G>C p.G125A (on ENST00000368888 / NM_001135638.2; = p.G112A on NM_003557.3) | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV62960400; called by muse, mutect2
- PON2 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as COSV56002098; called by muse, mutect2, varscan2
- PON3 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 59/356 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV55698895; called by muse, mutect2, varscan2
- POTEG | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 67/491 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1428488001; called by muse, mutect2, varscan2
- PPP1R3A | c.157T>C p.Y53H | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as rs764475684; called by muse, mutect2, varscan2
- PRSS35 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 67/404 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as rs776704051; called by muse, mutect2, varscan2
- PRSS38 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100816485; called by muse, mutect2, varscan2
- PXDNL | c.3767T>G p.V1256G | Missense Mutation (SNP) | VAF 35/335 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1160622670; called by muse, mutect2, varscan2
- PXN | c.1127C>T p.T376M (on ENST00000228307 / NM_001080855.3; = p.T342M on NM_002859.4) | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs755776323, COSV57220832; called by muse, mutect2, varscan2
- RALGAPB | c.3910G>C p.E1304Q | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV53440440; called by muse, mutect2, varscan2
- RARA | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs866777491, COSV54191573, COSV54196311; called by muse, mutect2, varscan2
- RBMXL2 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1309856621, COSV60978484; called by muse, mutect2, varscan2
- RPS6KB2 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1415732150; called by muse, mutect2
- SEPTIN14 | c.776G>T p.R259M | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66426569, COSV66429770; called by mutect2, varscan2
- SH2D4A | c.1222G>T p.V408L | Missense Mutation (SNP) | VAF 63/337 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs142937375; called by muse, mutect2, varscan2
- SIGLEC1 | c.2198G>C p.R733P | Missense Mutation (SNP) | VAF 29/419 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); catalogued as COSV52464943; called by muse, mutect2
- SLC10A1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV99384589; called by muse, varscan2
- SLC12A1 | c.3052C>G p.P1018A | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV66796806; called by muse, mutect2, varscan2
- SLC25A37 | c.346C>G p.P116A | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51564230; called by muse, mutect2
- SLC2A1 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 50/430 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs753161833, CM101700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SND1 | c.1319G>T p.C440F | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV61248510; called by muse, mutect2, varscan2
- SNTG2 | c.1237del p.E413Rfs*69 | Frame Shift Del (DEL) | VAF 40/326 reads (12%) | catalogued as COSV100421628, COSV58003059; called by mutect2, pindel, varscan2
- SNX11 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99070038; called by muse, mutect2, varscan2
- SOX11 | c.521C>A p.A174E | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as rs902373698; called by muse, mutect2, varscan2
- SQOR | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.053); catalogued as rs781675712; called by muse, mutect2, varscan2
- STIM1 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 91/451 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100331053, COSV56161686; called by muse, mutect2, varscan2
- STUM | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV64684126; called by muse, mutect2, varscan2
- TACC2 | c.6841G>T p.E2281* (on ENST00000334433; = p.E359* on NM_006997.4) | Nonsense Mutation (SNP) | VAF 49/291 reads (17%) | catalogued as COSV53291984; called by muse, mutect2, varscan2
- TDRD15 | c.931C>A p.Q311K | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.982); catalogued as COSV68266587; called by muse, mutect2, varscan2
- TECRL | c.918+1G>T p.X306_splice | Splice Site (SNP) | VAF 18/126 reads (14%) | catalogued as COSV67089754; called by muse, mutect2, varscan2
- TLR5 | c.1388G>C p.C463S | Missense Mutation (SNP) | VAF 75/299 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60558817; called by muse, mutect2, varscan2
- TMCC3 | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.872); catalogued as rs1303417409; called by muse, mutect2, varscan2
- TMEM108 | c.576G>T p.R192S | Missense Mutation (SNP) | VAF 70/426 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV58884752; called by muse, mutect2, varscan2
- TMEM30B | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 72/375 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs773957084; called by muse, mutect2, varscan2
- TMPRSS11D | c.1111C>A p.P371T | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99384946; called by muse, mutect2, varscan2
- TMPRSS13 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs778644730, COSV70625527; called by muse, mutect2, varscan2
- TSC22D2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100721179; called by muse, mutect2, varscan2
- TSHZ3 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.895); catalogued as COSV53665440; called by muse, mutect2
- TTC37 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.114); catalogued as rs1299718401; called by muse, varscan2
- VILL | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 75/416 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV52187565; called by muse, varscan2
- VWA5B2 | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.226); catalogued as rs566967537; called by muse, mutect2
- WDFY4 | c.3022C>A p.P1008T | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99065092; called by muse, mutect2, varscan2
- ZFAT | c.3220G>T p.D1074Y | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV64737409; called by muse, mutect2, varscan2
- ZIM3 | c.235C>G p.R79G | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54142834; called by muse, mutect2, varscan2
- ZNF208 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.592); catalogued as COSV68108478; called by mutect2, varscan2
- ZNF354C | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 42/265 reads (16%) | catalogued as COSV59607966; called by mutect2, varscan2
- ZNF536 | c.3305C>A p.P1102H | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as COSV62822581; called by muse, mutect2
- ZNF683 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as rs886844546; called by muse, mutect2, varscan2
- ZNF831 | c.2403G>T p.W801C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.43); catalogued as COSV64046745; called by muse, mutect2, varscan2
- ZNF835 | c.809G>C p.R270P | Missense Mutation (SNP) | VAF 44/281 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101606371; called by muse, mutect2, varscan2
- ZNF90 | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 63/375 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV69004230; called by muse, mutect2, varscan2
- ZSCAN1 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.782); catalogued as rs781616839; called by muse, mutect2, varscan2
- ZSCAN5A | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 38/355 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs754005392, COSV99570463; called by muse, mutect2, varscan2
- AATF | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ABCG8 | c.191G>A p.W64* | Nonsense Mutation (SNP) | VAF 47/400 reads (12%) | called by muse, varscan2
- ABL1 | c.2773G>T p.E925* | Nonsense Mutation (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- ABL2 | c.2941A>T p.K981* (on ENST00000502732 / NM_007314.4; = p.K966* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 36/440 reads (8%) | called by muse, mutect2
- ACAN | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 63/340 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- ADAD2 | c.1108G>T p.A370S (on ENST00000315906 / NM_001145400.2; = p.A452S on NM_139174.4) | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- ADAM23 | c.574-1G>T p.X192_splice | Splice Site (SNP) | VAF 30/227 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.1972T>C p.C658R | Missense Mutation (SNP) | VAF 91/419 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADARB2 | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY10 | c.2273A>T p.E758V | Missense Mutation (SNP) | VAF 49/678 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2
- ADCY5 | c.1866del p.G623Afs*33 | Frame Shift Del (DEL) | VAF 30/212 reads (14%) | called by mutect2, pindel*, varscan2
- ADNP2 | c.1609G>T p.G537C | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- AGL | c.3362G>T p.R1121M | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AHNAK | c.4453G>C p.V1485L | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AKR1A1 | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.019); called by muse, mutect2
- AKR1A1 | c.39G>T p.K13N | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2
- AMER3 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK3 | c.897G>T p.R299S | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- APBA2 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 98/485 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- APOB | c.6864C>A p.H2288Q | Missense Mutation (SNP) | VAF 28/297 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ARHGAP11A | c.2126A>T p.K709I | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2
- ARHGAP11A | c.2127A>T p.K709N | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- ARID3B | c.383C>A p.A128D | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2
- ASPSCR1 | c.995G>C p.R332P | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ASXL3 | c.1785G>T p.Q595H | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ASXL3 | c.2255C>A p.T752K | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ATP7B | c.4280A>T p.Q1427L | Missense Mutation (SNP) | VAF 93/499 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ATRX | c.6168A>T p.L2056F | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- B3GALT4 | c.466A>G p.S156G | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- BCAT1 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- BCL11B | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- BICRA | c.1783A>G p.M595V | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- C10orf71 | c.4196A>G p.Q1399R | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- C1QL2 | c.278del p.P93Lfs*29 | Frame Shift Del (DEL) | VAF 17/141 reads (12%) | called by mutect2, pindel, varscan2
- C1orf167 | c.569G>A p.R190K | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT deleterious (0.01); called by muse, mutect2
- C8orf74 | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CA6 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); called by muse, mutect2
- CACNA1E | c.6081G>T p.K2027N (on ENST00000367573 / NM_001205293.3; = p.K1984N on NM_000721.4) | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CACNA2D3 | c.557T>A p.V186D | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- CALR3 | c.598T>A p.W200R | Missense Mutation (SNP) | VAF 28/389 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAMTA1 | c.2792G>C p.G931A | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAPN14 | c.2026G>T p.E676* | Nonsense Mutation (SNP) | VAF 46/284 reads (16%) | called by muse, mutect2, varscan2
- CAPN6 | c.1000T>G p.F334V | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPSL | c.11C>A p.T4K | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- CARMIL2 | c.1633A>G p.R545G | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CBARP | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.019); called by muse, mutect2
- CCDC14 | c.2516G>T p.C839F (on ENST00000488653; = p.C791F on NM_022757.5) | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CCDC62 | c.1379A>T p.Q460L | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CCNA2 | c.722G>T p.R241M | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD109 | c.722T>A p.M241K | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD320 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 27/360 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.076); called by muse, mutect2
- CD4 | c.1048A>G p.K350E | Missense Mutation (SNP) | VAF 52/369 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CD48 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 96/512 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- CDH11 | c.2002G>A p.G668S | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CDH16 | c.1441C>A p.P481T | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- CDH7 | c.1968G>T p.E656D | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CDK8 | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CEACAM5 | c.59T>A p.L20H | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CENPF | c.2172G>T p.K724N | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CEP19 | c.286del p.E96Kfs*10 | Frame Shift Del (DEL) | VAF 53/419 reads (13%) | called by mutect2, pindel, varscan2
- CEP41 | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP251 | c.2792C>A p.S931Y | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CFAP46 | c.7392G>T p.Q2464H | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CFAP46 | c.4785del p.T1596Rfs*9 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- CHRD | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- CILP2 | c.1264A>T p.S422C | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- CILP2 | c.2324C>A p.P775H | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNGB1 | c.412+1G>T p.X138_splice | Splice Site (SNP) | VAF 28/431 reads (6%) | called by muse, mutect2
- CNGB1 | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 29/439 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CNTNAP2 | c.2326G>C p.D776H | Missense Mutation (SNP) | VAF 63/507 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- COL24A1 | c.3637G>T p.G1213W | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL26A1 | c.334G>T p.V112L (on ENST00000313669 / NM_001278563.3; = p.V110L on NM_133457.4) | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- COL3A1 | c.3185G>T p.G1062V | Missense Mutation (SNP) | VAF 57/479 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL3A1 | c.3308C>T p.A1103V | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- COL6A2 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
- COMP | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 136/746 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPAMD8 | c.3857G>T p.W1286L (on ENST00000651564; = p.W1239L on NM_015692.5) | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE7 | c.1240C>A p.L414M | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CPXM2 | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CR2 | c.1133C>A p.A378D | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.12); called by mutect2, varscan2
- CRAMP1 | c.1957C>G p.Q653E | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- CTRB2 | c.236+1G>T p.X79_splice | Splice Site (SNP) | VAF 20/246 reads (8%) | called by muse, varscan2
- CUBN | c.5487G>T p.W1829C | Missense Mutation (SNP) | VAF 66/490 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CYP2D7 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- DAB2IP | c.1875G>T p.W625C (on ENST00000408936; = p.W597C on NM_032552.3) | Missense Mutation (SNP) | VAF 104/291 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- DNAAF1 | c.1925C>A p.S642Y | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- DNAH5 | c.3466A>T p.I1156F | Missense Mutation (SNP) | VAF 48/299 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH7 | c.6872A>T p.N2291I | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNHD1 | c.8903G>C p.G2968A | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- DOCK10 | c.4127T>A p.L1376H | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK4 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DOCK9 | c.1416A>G p.I472M (on ENST00000376460 / NM_001366676.2; = p.I473M on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- DQX1 | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.204); called by muse, varscan2
- DRD1 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 53/323 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSPP | c.1036A>T p.K346* | Nonsense Mutation (SNP) | VAF 17/268 reads (6%) | called by muse, mutect2
- DSTYK | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.897G>T p.L299F | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUXA | c.611G>A p.W204* | Nonsense Mutation (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- DYNC2I1 | c.935+1G>T p.X312_splice | Splice Site (SNP) | VAF 22/179 reads (12%) | called by muse, mutect2, varscan2
- EFS | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ELMO1 | c.1849G>T p.V617L | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- EMP2 | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2
- ENG | c.117G>T p.R39S | Missense Mutation (SNP) | VAF 110/411 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ENOX1 | c.590-1G>T p.X197_splice | Splice Site (SNP) | VAF 20/100 reads (20%) | called by muse, varscan2
- EPHA4 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EPM2A | c.540G>T p.M180I | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- EVI5L | c.507G>T p.K169N | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- FAM160A1 | c.1598A>C p.E533A | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAM78B | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2
- FAT4 | c.14533G>T p.D4845Y | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- FBLN2 | c.3152G>T p.C1051F | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN2 | c.1265del p.P422Qfs*67 | Frame Shift Del (DEL) | VAF 67/380 reads (18%) | called by mutect2, pindel, varscan2
- FCRL2 | c.1112A>T p.N371I | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2
- FCRL5 | c.2926C>T p.H976Y | Missense Mutation (SNP) | VAF 39/546 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); called by muse, mutect2
- FER1L6 | c.4370G>T p.G1457V | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FLNB | c.5729-1G>T p.X1910_splice | Splice Site (SNP) | VAF 59/354 reads (17%) | called by muse, mutect2, varscan2
- FMO4 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 51/413 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- FNIP2 | c.1577G>T p.R526L | Missense Mutation (SNP) | VAF 90/456 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXA3 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 55/306 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FRMPD2 | c.2995C>G p.R999G | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.16583G>T p.C5528F | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- FYB1 | c.1760C>A p.P587H | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABBR2 | c.2788G>T p.V930L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GALNT3 | c.698del p.H233Lfs*4 | Frame Shift Del (DEL) | VAF 40/241 reads (17%) | called by mutect2, pindel, varscan2
- GARRE1 | c.1550A>T p.Q517L | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.035); called by muse, mutect2
- GCNA | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GCNT1 | c.1055G>T p.R352M | Missense Mutation (SNP) | VAF 120/458 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCNT1 | c.1056G>T p.R352S | Missense Mutation (SNP) | VAF 121/460 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLI1 | c.432del p.S146Rfs*19 | Frame Shift Del (DEL) | VAF 61/443 reads (14%) | called by mutect2, pindel, varscan2
- GNAL | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.635); called by muse, mutect2
- H2BC7 | c.364T>A p.Y122N | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- HADHA | c.1609A>T p.I537F | Missense Mutation (SNP) | VAF 67/609 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HDX | c.1034C>A p.P345Q | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HEATR1 | c.2954A>T p.Q985L | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HELZ2 | c.5104G>T p.D1702Y (on ENST00000467148 / NM_001037335.2; = p.D1133Y on NM_033405.3) | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HGF | c.1839T>A p.S613R | Missense Mutation (SNP) | VAF 87/482 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- HIC2 | c.407G>C p.R136P | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HK3 | c.1093G>T p.V365F | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- HMCN1 | c.8845G>T p.A2949S | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HOXA5 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- HRH2 | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.104); called by muse, mutect2
- HSPA12A | c.601A>T p.I201F | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- HTATSF1 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); called by muse, varscan2
- HTR1A | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 104/825 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- HTR3C | c.532T>A p.F178I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HUWE1 | c.5228G>T p.G1743V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- IGF2BP1 | c.221T>A p.V74E | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- IGHV1-3 | c.46+1G>T p.X16_splice | Splice Site (SNP) | VAF 57/293 reads (19%) | called by muse, mutect2, varscan2
- IL18RAP | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- IL1A | c.365T>A p.V122E | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- ILDR2 | c.994+1G>T p.X332_splice | Splice Site (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2
- IQSEC1 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IQSEC2 | c.2279G>T p.G760V (on ENST00000642864 / NM_001111125.3; = p.G555V on NM_015075.2) | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ITGA6 | c.2942G>T p.R981L (on ENST00000442250; = p.R942L on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/483 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ITLN2 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 14/325 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- KCNA1 | c.1003A>T p.I335F | Missense Mutation (SNP) | VAF 59/373 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KCNN3 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 41/512 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2
- KDM3B | c.1964A>G p.Q655R | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- KIAA1109 | c.10012A>T p.N3338Y | Missense Mutation (SNP) | VAF 26/367 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- KIF21B | c.298G>C p.G100R | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF2B | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KPNB1 | c.2408A>T p.H803L | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRBA1 | c.1237C>G p.P413A | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LBX1 | c.139G>T p.V47L | Missense Mutation (SNP) | VAF 40/359 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LEFTY2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 82/427 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- LMNB2 | c.559-1G>T p.X187_splice | Splice Site (SNP) | VAF 44/625 reads (7%) | called by muse, mutect2
- LPO | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 82/471 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- LVRN | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAB21L2 | c.948C>A p.C316* | Nonsense Mutation (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- MAP2 | c.2689dup p.Y897Lfs*5 | Frame Shift Ins (INS) | VAF 30/262 reads (11%) | called by pindel, varscan2
- MCF2L | c.2783C>G p.P928R (on ENST00000375608; = p.P896R on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MCRS1 | c.1087-2A>T p.X363_splice | Splice Site (SNP) | VAF 27/208 reads (13%) | called by muse, mutect2, varscan2
- MEIS3 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MIA2 | c.1558G>T p.G520C | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MMP19 | c.1089C>G p.F363L | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- MRM2 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MST1R | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTBP | c.415T>A p.S139T | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.298); called by muse, mutect2
- MUC12 | c.2954C>A p.T985K (on ENST00000379442; = p.T842K on NM_001164462.1) | Missense Mutation (SNP) | VAF 42/709 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.413); called by muse, mutect2
- MUC16 | c.42016G>A p.G14006S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MUC16 | c.13508del p.P4503Lfs*2 | Frame Shift Del (DEL) | VAF 21/167 reads (13%) | called by mutect2, pindel, varscan2
- MUC17 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYBPC2 | c.1020C>A p.F340L | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYH2 | c.4322C>A p.T1441K | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MYL10 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MYL12B | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.068); called by muse, mutect2
- MYLK | c.1364G>T p.R455M | Missense Mutation (SNP) | VAF 70/384 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MYO15A | c.476G>T p.W159L | Missense Mutation (SNP) | VAF 50/317 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MYO1G | c.2306G>T p.G769V | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO7A | c.3080T>A p.L1027H | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYOG | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.023); called by muse, varscan2
- MYOM1 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 117/467 reads (25%) | called by muse, mutect2, varscan2
- MYOT | c.321C>A p.Y107* | Nonsense Mutation (SNP) | VAF 34/201 reads (17%) | called by muse, mutect2, varscan2
- MYT1L | c.2375A>T p.E792V | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- NAT8L | c.342C>G p.H114Q | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- NBPF14 | c.8546G>T p.G2849V | Missense Mutation (SNP) | VAF 25/710 reads (4%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.543); called by muse, mutect2
- NCAN | c.3595C>A p.P1199T | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCCRP1 | c.453-2A>T p.X151_splice | Splice Site (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- NCCRP1 | c.453-1G>T p.X151_splice | Splice Site (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- NCKAP1L | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- NCKAP1L | c.1749C>A p.C583* | Nonsense Mutation (SNP) | VAF 46/287 reads (16%) | called by muse, mutect2, varscan2
- NCOA6 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.01); called by muse, mutect2
- NDUFS7 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); called by muse, mutect2
- NFIC | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 41/399 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NIPAL1 | c.598A>T p.M200L | Missense Mutation (SNP) | VAF 29/352 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.044); called by muse, mutect2
- NLGN2 | c.1734G>T p.K578N | Missense Mutation (SNP) | VAF 118/658 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- NLRP7 | c.2263C>A p.L755M (on ENST00000340844 / NM_206828.3; = p.L727M on NM_139176.3) | Missense Mutation (SNP) | VAF 41/504 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.108); called by muse, mutect2
- NOL9 | c.624G>T p.R208S | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- NPHP1 | c.726A>T p.Q242H | Missense Mutation (SNP) | VAF 43/472 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- NPSR1 | c.1127C>G p.P376R | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NPTXR | c.794A>T p.Q265L | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.629); called by muse, mutect2
- NRG2 | c.1823A>G p.H608R | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- NUP42 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- NUTM2A | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 34/630 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2
- NUTM2F | c.864G>C p.E288D | Missense Mutation (SNP) | VAF 101/384 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NWD1 | c.496+8del | Splice Region (DEL) | VAF 49/329 reads (15%) | called by mutect2, pindel, varscan2
- NYAP1 | c.222C>A p.C74* | Nonsense Mutation (SNP) | VAF 25/187 reads (13%) | called by muse, mutect2, varscan2
- OR10H1 | c.733C>A p.H245N | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR10H3 | c.449G>T p.W150L | Missense Mutation (SNP) | VAF 54/294 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR11L1 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 38/560 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR1D2 | c.323T>A p.V108E | Missense Mutation (SNP) | VAF 88/565 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- OR2G3 | c.487A>G p.T163A | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- OR2L8 | c.216C>A p.Y72* | Nonsense Mutation (SNP) | VAF 26/439 reads (6%) | called by muse, mutect2
- OR2M3 | c.609T>A p.C203* | Nonsense Mutation (SNP) | VAF 36/478 reads (8%) | called by muse, mutect2
- OR2T1 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 57/315 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- OR2T34 | c.569T>A p.L190Q | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- OR2T34 | c.229A>T p.M77L | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4K1 | c.527G>T p.S176I | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR4L1 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR5B3 | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR6P1 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2
- P3H3 | c.905C>A p.A302D | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PCDHB11 | c.340A>T p.T114S | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PCDHB2 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- PDE6B | c.674T>A p.L225Q | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PGM5 | c.1479+1G>A p.X493_splice | Splice Site (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
- PHF21B | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PHOX2B | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 61/250 reads (24%) | called by muse, varscan2
- PIGQ | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PIK3R1 | c.1118+1G>T p.X373_splice (on ENST00000521381 / NM_181523.3; = p.X103_splice on NM_181504.4) | Splice Site (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- PLAU | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- PLCB4 | c.2188C>A p.P730T | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- POLE | c.3204G>T p.M1068I | Missense Mutation (SNP) | VAF 69/358 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- POMC | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPARA | c.1305G>C p.Q435H | Missense Mutation (SNP) | VAF 37/371 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PPP1R37 | c.1841A>T p.D614V | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.166); called by muse, mutect2
- PRAM1 | c.1155dup p.S386Qfs*111 | Frame Shift Ins (INS) | VAF 37/329 reads (11%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 55/885 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2
- PRDM16 | c.1853C>A p.T618N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- PRF1 | c.74C>A p.T25K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PRKCG | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 58/590 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2
- PRPF6 | c.840G>T p.M280I | Missense Mutation (SNP) | VAF 58/353 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTCH1 | c.1154T>A p.I385N | Missense Mutation (SNP) | VAF 131/429 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PTPRE | c.1861A>G p.T621A | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- PXMP4 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAG2 | c.971A>T p.N324I | Missense Mutation (SNP) | VAF 53/621 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- RALGAPA1 | c.3217G>T p.G1073* | Nonsense Mutation (SNP) | VAF 19/182 reads (10%) | called by muse, mutect2, varscan2
- RASGRP4 | c.90C>A p.H30Q | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); called by muse, mutect2
- RBM20 | c.1029C>A p.H343Q | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RCBTB2 | c.1082C>G p.A361G | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RET | c.553T>A p.F185I | Missense Mutation (SNP) | VAF 51/341 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- RHPN1 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPE65 | c.1282G>T p.G428W | Missense Mutation (SNP) | VAF 48/482 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RPL37A | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2
- RYR1 | c.11879T>G p.V3960G | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- RYR2 | c.3077A>C p.N1026T | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RYR2 | c.10727T>A p.V3576E | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SACM1L | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- SAMD11 | c.498G>T p.R166S | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- SCN10A | c.3041G>T p.G1014V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPING1 | c.1067T>G p.V356G | Missense Mutation (SNP) | VAF 85/449 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SETD4 | c.902-2A>G p.X301_splice | Splice Site (SNP) | VAF 21/104 reads (20%) | called by mutect2, varscan2
- SF3B1 | c.1975C>A p.Q659K | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SFRP4 | c.666G>T p.E222D | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SGIP1 | c.2131A>G p.T711A | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHISA9 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 49/404 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHOX | c.800C>A p.A267D | Missense Mutation (SNP) | VAF 77/371 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SLC12A1 | c.2882C>A p.S961Y | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- SLC13A1 | c.1687G>T p.A563S | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- SLC16A2 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 21/159 reads (13%) | called by muse, mutect2, varscan2
- SLC25A39 | c.46G>T p.V16L | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SLC25A48 | c.676G>A p.A226T (on ENST00000650267; = p.A172T on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SLC26A7 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC29A3 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 45/406 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC4A8 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC5A8 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SLFN5 | c.1966A>T p.T656S | Missense Mutation (SNP) | VAF 28/303 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.868); called by muse, mutect2
- SLITRK1 | c.1781A>T p.K594I | Missense Mutation (SNP) | VAF 38/488 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.057); called by muse, mutect2
- SMIM2 | c.42C>A p.H14Q | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.412); called by muse, mutect2
- SNX11 | c.132C>T p.T44= | Splice Region (SNP) | VAF 40/278 reads (14%) | called by muse, mutect2, varscan2
- SORCS1 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA31A6 | c.2111C>A p.P704H | Missense Mutation (SNP) | VAF 62/470 reads (13%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- SSC5D | c.707G>T p.C236F | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SSC5D | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2
- ST6GALNAC5 | c.345C>A p.D115E | Missense Mutation (SNP) | VAF 8/178 reads (4%) | PolyPhen possibly damaging (0.773); called by muse, mutect2
- STK4 | c.301G>T p.V101F | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SYMPK | c.1504G>C p.V502L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SYNE1 | c.4574A>T p.K1525M (on ENST00000367255 / NM_182961.4; = p.K1532M on NM_033071.3) | Missense Mutation (SNP) | VAF 107/605 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TAF3 | c.2568G>C p.V856= | Splice Region (SNP) | VAF 49/351 reads (14%) | called by muse, mutect2, varscan2
- TARBP1 | c.1918G>T p.V640F | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2
- TAS2R7 | c.659C>A p.T220K | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- TBX3 | c.869C>A p.T290N (on ENST00000257566 / NM_016569.4; = p.T270N on NM_005996.4) | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TCERG1L | c.1412C>G p.T471S | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TCF23 | c.117G>T p.R39S | Missense Mutation (SNP) | VAF 43/406 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TCF23 | c.523T>A p.S175T | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD12 | c.1244G>A p.C415Y | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TDRD15 | c.2552C>A p.P851Q | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM2 | c.374C>A p.P125Q | Missense Mutation (SNP) | VAF 59/386 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEX13C | c.1182C>G p.D394E | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- THBS2 | c.2162C>A p.P721H | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- THEM6 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- THSD7A | c.4748C>A p.S1583Y | Missense Mutation (SNP) | VAF 60/395 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- TMEM178B | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM178B | c.664T>A p.C222S | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); called by muse, varscan2
- TMEM202 | c.20T>A p.L7* | Nonsense Mutation (SNP) | VAF 22/158 reads (14%) | called by muse, varscan2
- TMEM44 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- TMPRSS11E | c.878T>A p.V293E | Missense Mutation (SNP) | VAF 29/371 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMPRSS15 | c.2533A>T p.M845L | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, varscan2
- TMTC1 | c.1081G>T p.A361S (on ENST00000539277 / NM_001193451.2; = p.A253S on NM_175861.3) | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- TNFSF13B | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TOP2B | c.3787G>T p.G1263C (on ENST00000264331 / NM_001330700.2; = p.G1258C on NM_001068.3) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- TPRX1 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- TRAV12-3 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 31/253 reads (12%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.4993G>T p.D1665Y | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPOAP1 | c.4325G>T p.R1442L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TTLL10 | c.1741A>T p.S581C | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- TUFT1 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- UBFD1 | c.530A>T p.E177V | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- UGGT1 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- UGT2B7 | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC80 | c.8245C>T p.L2749F | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.991); called by muse, varscan2
- USP5 | c.1762+1G>T p.X588_splice | Splice Site (SNP) | VAF 51/318 reads (16%) | called by muse, mutect2, varscan2
- VAV1 | c.246C>A p.C82* | Nonsense Mutation (SNP) | VAF 27/253 reads (11%) | called by muse, mutect2, varscan2
- VPS13A | c.4613G>T p.W1538L | Missense Mutation (SNP) | VAF 92/380 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); called by mutect2, varscan2
- VPS13A | c.4614G>T p.W1538C | Missense Mutation (SNP) | VAF 94/389 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- VSIG4 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- VWA3B | c.1403C>A p.T468N | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- VWA5B1 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- VWF | c.4387G>T p.E1463* | Nonsense Mutation (SNP) | VAF 57/324 reads (18%) | called by muse, mutect2, varscan2
- WAS | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- WASHC2C | c.1951C>A p.L651I | Missense Mutation (SNP) | VAF 44/439 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WASHC2C | c.1952T>A p.L651H | Missense Mutation (SNP) | VAF 45/440 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- WASHC4 | c.1039G>T p.V347L | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WDR59 | c.2797G>T p.G933* | Nonsense Mutation (SNP) | VAF 33/480 reads (7%) | called by muse, mutect2
- WNK1 | c.4524G>T p.Q1508H (on ENST00000315939 / NM_018979.4; = p.Q1261H on NM_014823.3) | Missense Mutation (SNP) | VAF 65/437 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- XKR5 | c.1592A>C p.Q531P | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB41 | c.1694A>G p.H565R | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZDHHC14 | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF229 | c.594T>A p.D198E | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2
- ZNF394 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF445 | c.1487A>T p.H496L | Missense Mutation (SNP) | VAF 89/507 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF467 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF644 | c.1436A>T p.E479V | Missense Mutation (SNP) | VAF 55/539 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF853 | c.1282G>T p.G428W | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF860 | c.1655A>T p.H552L | Missense Mutation (SNP) | VAF 53/344 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA12 | c.960G>T p.L320= | Silent (SNP) | VAF 52/456 reads (11%) | called by muse, mutect2, varscan2
- ADAM22 | c.1995A>G p.E665= | Silent (SNP) | VAF 42/300 reads (14%) | called by muse, varscan2
- ADGRA2 | c.2952C>T p.P984= | Silent (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- ADGRB3 | c.1317G>T p.G439= | Silent (SNP) | VAF 22/128 reads (17%) | called by muse, varscan2
- AKR7A2 | c.744G>T p.V248= | Silent (SNP) | VAF 46/544 reads (8%) | called by muse, mutect2
- AL592490.1 | c.2821C>A p.R941= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV69426284; called by muse, mutect2, varscan2
- ANK1 | c.1908G>T p.V636= | Silent (SNP) | VAF 69/408 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.369C>T p.L123= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as rs1428570227; called by muse, mutect2, varscan2
- ASXL3 | c.3519C>G p.A1173= | Silent (SNP) | VAF 28/289 reads (10%) | catalogued as COSV52474317; called by muse, mutect2
- BIVM-ERCC5 | c.4209G>A p.L1403= | Silent (SNP) | VAF 52/278 reads (19%) | called by muse, mutect2, varscan2
- C10orf71 | c.3147C>A p.V1049= | Silent (SNP) | VAF 26/188 reads (14%) | called by muse, mutect2, varscan2
- CFAP46 | c.2673G>T p.S891= | Silent (SNP) | VAF 29/178 reads (16%) | called by muse, mutect2, varscan2
- CGREF1 | c.411T>A p.A137= | Silent (SNP) | VAF 45/331 reads (14%) | called by muse, mutect2, varscan2
- CNTN5 | c.2199C>A p.A733= | Silent (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- COL12A1 | c.696G>T p.T232= | Silent (SNP) | VAF 41/211 reads (19%) | catalogued as COSV59392985; called by muse, mutect2, varscan2
- COL14A1 | c.2178T>A p.P726= | Silent (SNP) | VAF 44/266 reads (17%) | called by muse, mutect2, varscan2
- COL1A2 | c.621T>C p.N207= | Silent (SNP) | VAF 38/305 reads (12%) | called by muse, mutect2, varscan2
- COL1A2 | c.1647T>A p.P549= | Silent (SNP) | VAF 88/572 reads (15%) | called by muse, mutect2, varscan2
- COL20A1 | c.3657C>A p.P1219= | Silent (SNP) | VAF 37/188 reads (20%) | called by muse, mutect2, varscan2
- CPNE4 | c.873C>T p.H291= | Silent (SNP) | VAF 32/192 reads (17%) | catalogued as rs1363461993, COSV70190856, COSV70200418; called by muse, varscan2
- CTTNBP2 | c.3207G>T p.A1069= | Silent (SNP) | VAF 28/249 reads (11%) | called by muse, mutect2, varscan2
- CYP3A7 | c.24C>A p.A8= | Silent (SNP) | VAF 87/508 reads (17%) | catalogued as rs759179797; called by mutect2, varscan2
- DEPTOR | c.1191G>T p.R397= | Silent (SNP) | VAF 44/281 reads (16%) | called by muse, mutect2, varscan2
- DSCAM | c.708C>A p.A236= | Silent (SNP) | VAF 18/127 reads (14%) | called by muse, mutect2, varscan2
- ECE2 | c.81A>T p.A27= | Silent (SNP) | VAF 48/381 reads (13%) | called by muse, mutect2, varscan2
- EDIL3 | c.1029G>T p.T343= | Silent (SNP) | VAF 60/400 reads (15%) | catalogued as rs765794931; called by muse, mutect2, varscan2
- ELFN1 | c.768G>T p.A256= | Silent (SNP) | VAF 37/226 reads (16%) | catalogued as rs561886039; called by muse, mutect2, varscan2
- ELOC | c.279C>T p.F93= | Silent (SNP) | VAF 31/178 reads (17%) | called by muse, mutect2, varscan2
- EMILIN3 | c.1767C>T p.V589= | Silent (SNP) | VAF 14/157 reads (9%) | called by muse, mutect2
- EPHB1 | c.1065C>A p.T355= | Silent (SNP) | VAF 30/197 reads (15%) | catalogued as rs372552203; called by muse, varscan2
- ERBIN | c.3741A>G p.P1247= | Silent (SNP) | VAF 38/204 reads (19%) | called by muse, mutect2, varscan2
- F11 | c.636C>T p.D212= | Silent (SNP) | VAF 28/375 reads (7%) | called by muse, mutect2
- FCRL5 | c.2550A>T p.T850= | Silent (SNP) | VAF 62/236 reads (26%) | called by muse, mutect2, varscan2
- FLG | c.3198C>G p.S1066= | Silent (SNP) | VAF 124/622 reads (20%) | called by mutect2, varscan2
- GALC | c.1368G>C p.L456= | Silent (SNP) | VAF 43/235 reads (18%) | called by muse, mutect2, varscan2
- GLRA1 | c.585C>A p.I195= | Silent (SNP) | VAF 69/424 reads (16%) | catalogued as rs370809444, COSV51007423; called by muse, mutect2, varscan2
- GPR26 | c.531C>T p.H177= | Silent (SNP) | VAF 16/299 reads (5%) | catalogued as rs1564728860, COSV99500917; called by muse, mutect2
- GRIK1 | c.2368C>A p.R790= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as COSV58731753; called by muse, mutect2
- HMCN2 | c.5514C>A p.P1838= | Silent (SNP) | VAF 65/221 reads (29%) | called by muse, mutect2, varscan2
- HOXA3 | c.1035C>T p.H345= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- HSPG2 | c.1410G>A p.K470= | Silent (SNP) | VAF 62/651 reads (10%) | catalogued as rs1454895598; called by muse, mutect2
- HVCN1 | c.516C>A p.I172= | Silent (SNP) | VAF 60/350 reads (17%) | catalogued as rs749592355; called by mutect2, varscan2
- IGKV3-11 | c.24C>A p.L8= | Silent (SNP) | VAF 37/338 reads (11%) | catalogued as rs774478157; called by muse, mutect2, varscan2
- IGLV3-19 | c.294G>T p.A98= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as rs370241958; called by muse, mutect2
- IL17RE | c.1752C>T p.A584= | Silent (SNP) | VAF 16/91 reads (18%) | called by muse, mutect2, varscan2
- IL1R1 | c.1527A>G p.K509= | Silent (SNP) | VAF 17/249 reads (7%) | called by muse, mutect2
- INPP4B | c.2580C>A p.I860= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- INSYN2B | c.213C>A p.T71= | Silent (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- ITPR1 | c.1977C>T p.P659= (on ENST00000354582; = p.P644= on NM_002222.7) | Silent (SNP) | VAF 29/151 reads (19%) | called by muse, mutect2, varscan2
- KCNMB1 | c.12G>A p.K4= | Silent (SNP) | VAF 48/241 reads (20%) | catalogued as rs1295434154; called by muse, mutect2, varscan2
- KCNN1 | c.624G>T p.T208= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as rs1178549741; called by muse, mutect2, varscan2
- KCTD15 | c.87G>C p.R29= | Silent (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2
- KIAA0319L | c.1995C>T p.F665= | Silent (SNP) | VAF 26/263 reads (10%) | called by muse, mutect2
- KIF1A | c.2856C>T p.D952= | Silent (SNP) | VAF 29/201 reads (14%) | catalogued as rs761993869; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIF5A | c.2685G>A p.Q895= | Silent (SNP) | VAF 57/412 reads (14%) | called by muse, mutect2, varscan2
- KRT72 | c.834G>T p.T278= | Silent (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- LIG1 | c.2031G>T p.R677= | Silent (SNP) | VAF 51/330 reads (15%) | called by muse, mutect2, varscan2
- LPA | c.2913G>T p.S971= | Silent (SNP) | VAF 73/449 reads (16%) | catalogued as rs752757407, COSV60298423; called by muse, mutect2, varscan2
- LPL | c.1338T>A p.S446= | Silent (SNP) | VAF 44/461 reads (10%) | called by muse, mutect2
- LRRTM1 | c.1428C>A p.T476= | Silent (SNP) | VAF 30/402 reads (7%) | called by muse, mutect2
- MAGI1 | c.3306A>G p.P1102= (on ENST00000402939 / NM_001033057.2; = p.P1131= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/428 reads (14%) | called by muse, mutect2, varscan2
- MEGF8 | c.2118G>T p.T706= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as rs947195336, COSV52080699; called by muse, mutect2
- MEP1B | c.1839T>C p.C613= | Silent (SNP) | VAF 23/178 reads (13%) | called by muse, mutect2, varscan2
- METTL21C | c.687C>A p.T229= | Silent (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- MFHAS1 | c.954G>T p.L318= | Silent (SNP) | VAF 43/328 reads (13%) | catalogued as COSV99359594; called by muse, mutect2, varscan2
- MIGA2 | c.153G>T p.T51= | Silent (SNP) | VAF 105/348 reads (30%) | catalogued as rs567781829; called by muse, mutect2, varscan2
- MPC1L | c.111C>A p.G37= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1191643806; called by muse, varscan2
- MTTP | c.870G>T p.V290= | Silent (SNP) | VAF 44/422 reads (10%) | called by mutect2, varscan2
- MUC16 | c.27939C>G p.P9313= | Silent (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- MUC16 | c.17631C>G p.T5877= | Silent (SNP) | VAF 29/177 reads (16%) | called by muse, mutect2, varscan2
- MUC16 | c.4869A>T p.T1623= | Silent (SNP) | VAF 26/344 reads (8%) | called by muse, mutect2
- NAA11 | c.219C>A p.T73= | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as COSV54516081; called by muse, mutect2, varscan2
- NEU2 | c.732C>A p.V244= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99290502; called by muse, mutect2, varscan2
- NGF | c.189G>T p.V63= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as COSV65686787, COSV65687921; called by muse, mutect2, varscan2
- NKIRAS2 | c.472C>T p.L158= | Silent (SNP) | VAF 67/438 reads (15%) | called by muse, mutect2, varscan2
- NOA1 | c.1519T>C p.L507= | Silent (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- OBSCN | c.2559C>T p.H853= | Silent (SNP) | VAF 49/334 reads (15%) | catalogued as rs373110587; called by muse, mutect2, varscan2
- OR2A12 | c.873T>G p.L291= | Silent (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2
- OR4K14 | c.546C>A p.L182= | Silent (SNP) | VAF 47/311 reads (15%) | called by muse, mutect2, varscan2
- OR8H1 | c.540G>A p.T180= | Silent (SNP) | VAF 47/196 reads (24%) | catalogued as COSV57295895; called by muse, mutect2, varscan2
- PCDHB13 | c.1590C>T p.R530= | Silent (SNP) | VAF 132/708 reads (19%) | catalogued as COSV53398645; called by muse, mutect2, varscan2
- PCDHB15 | c.2166G>A p.V722= | Silent (SNP) | VAF 57/344 reads (17%) | called by muse, mutect2, varscan2
- PCDHB3 | c.516C>A p.I172= | Silent (SNP) | VAF 30/253 reads (12%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.1206G>T p.V402= | Silent (SNP) | VAF 25/172 reads (15%) | called by muse, mutect2, varscan2
- PCMTD2 | c.756G>T p.R252= | Silent (SNP) | VAF 35/170 reads (21%) | called by muse, mutect2, varscan2
- PEAR1 | c.1920G>T p.L640= | Silent (SNP) | VAF 12/272 reads (4%) | called by muse, mutect2
- PLEC | c.9309G>A p.Q3103= (on ENST00000322810 / NM_201380.4; = p.Q2993= on NM_000445.5) | Silent (SNP) | VAF 79/572 reads (14%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.876C>A p.I292= | Silent (SNP) | VAF 34/235 reads (14%) | catalogued as rs782154349; called by muse, mutect2, varscan2
- POTEA | c.381C>T p.V127= | Silent (SNP) | VAF 31/165 reads (19%) | called by muse, mutect2, varscan2
- PPL | c.4032G>C p.S1344= | Silent (SNP) | VAF 35/380 reads (9%) | catalogued as COSV52170706; called by muse, mutect2
- PPP1R16B | c.1395C>T p.A465= | Silent (SNP) | VAF 70/505 reads (14%) | called by muse, mutect2, varscan2
- PREX1 | c.2830C>T p.L944= | Silent (SNP) | VAF 48/247 reads (19%) | called by muse, mutect2, varscan2
- PREX1 | c.2676C>T p.A892= | Silent (SNP) | VAF 14/171 reads (8%) | called by muse, mutect2
- PTPRO | c.1686G>T p.V562= | Silent (SNP) | VAF 49/259 reads (19%) | catalogued as rs533041120; called by muse, mutect2, varscan2
- PTX4 | c.1332C>T p.I444= (on ENST00000447419 / NM_001328608.2; = p.I439= on NM_001013658.1) | Silent (SNP) | VAF 78/261 reads (30%) | catalogued as rs370288044; called by muse, mutect2, varscan2
- RAC2 | c.520C>A p.R174= | Silent (SNP) | VAF 40/316 reads (13%) | called by muse, mutect2, varscan2
- RELN | c.3921A>T p.I1307= | Silent (SNP) | VAF 60/466 reads (13%) | called by muse, mutect2, varscan2
- RORC | c.1101G>T p.R367= | Silent (SNP) | VAF 17/260 reads (7%) | called by muse, mutect2
- SCARF1 | c.795T>C p.C265= | Silent (SNP) | VAF 14/173 reads (8%) | called by muse, mutect2
- SCN10A | c.1492C>A p.R498= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2
- SCN7A | c.3316C>A p.R1106= | Silent (SNP) | VAF 56/383 reads (15%) | catalogued as rs774846956, COSV101313249; called by muse, varscan2
- SDC3 | c.1020G>T p.A340= | Silent (SNP) | VAF 36/345 reads (10%) | called by muse, mutect2, varscan2
- SLC36A2 | c.765G>T p.R255= | Silent (SNP) | VAF 68/502 reads (14%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.780T>A p.L260= | Silent (SNP) | VAF 82/383 reads (21%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.744G>T p.P248= | Silent (SNP) | VAF 90/278 reads (32%) | catalogued as rs370494405, COSV57793610, COSV57796058; called by muse, varscan2
- SPTAN1 | c.1314G>A p.V438= | Silent (SNP) | VAF 135/478 reads (28%) | catalogued as rs751295099, COSV63985836; called by muse, mutect2, varscan2
- STARD8 | c.2796G>T p.L932= | Silent (SNP) | VAF 36/110 reads (33%) | called by muse, mutect2, varscan2
- TBC1D9 | c.1611A>T p.T537= | Silent (SNP) | VAF 38/207 reads (18%) | called by muse, mutect2, varscan2
- TCL1B | c.276C>A p.P92= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV61552396; called by muse, mutect2, varscan2
- TENM3 | c.180C>A p.G60= | Silent (SNP) | VAF 36/383 reads (9%) | catalogued as rs1294501419; called by muse, mutect2
- TEX15 | c.429A>G p.R143= (on ENST00000638951; = p.R139= on NM_001350162.2) | Silent (SNP) | VAF 40/294 reads (14%) | called by muse, mutect2, varscan2
- TGIF2LX | c.600G>T p.P200= | Silent (SNP) | VAF 60/238 reads (25%) | catalogued as COSV52213488; called by muse, mutect2, varscan2
- THBS2 | c.921C>A p.L307= | Silent (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
- THSD7A | c.2379T>C p.S793= | Silent (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- TKTL2 | c.750G>T p.R250= | Silent (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- TNFRSF8 | c.582A>G p.V194= | Silent (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- TNFSF13B | c.144G>T p.L48= | Silent (SNP) | VAF 37/246 reads (15%) | catalogued as COSV65516627; called by muse, mutect2, varscan2
- TP53BP2 | c.540G>A p.E180= (on ENST00000343537 / NM_001031685.3; = p.E51= on NM_005426.2) | Silent (SNP) | VAF 46/373 reads (12%) | catalogued as rs1451295486; called by muse, mutect2, varscan2
- TRBV27 | c.283C>T p.L95= | Silent (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- TRIM36 | c.102A>T p.P34= | Silent (SNP) | VAF 45/234 reads (19%) | called by muse, mutect2, varscan2
- TRPC7 | c.177C>A p.V59= | Silent (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- TRPM8 | c.1869C>A p.T623= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV61221752; called by muse, mutect2
- TUBB4A | c.933G>T p.L311= | Silent (SNP) | VAF 65/416 reads (16%) | catalogued as rs200310489; called by muse, mutect2, varscan2
- UGT1A6 | c.1317C>T p.I439= | Silent (SNP) | VAF 54/352 reads (15%) | catalogued as COSV59381519; called by muse, mutect2, varscan2
- URB2 | c.4476G>T p.S1492= | Silent (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- WDR86 | c.351G>C p.R117= | Silent (SNP) | VAF 22/424 reads (5%) | catalogued as COSV57844155; called by muse, mutect2
- XIRP2 | c.5733T>A p.T1911= (on ENST00000628543; = p.T2086= on NM_152381.6) | Silent (SNP) | VAF 42/267 reads (16%) | catalogued as COSV54727513; called by muse, mutect2, varscan2
- ZFP57 | c.36G>A p.Q12= | Silent (SNP) | VAF 82/429 reads (19%) | called by muse, mutect2, varscan2
- ZNF394 | c.906G>A p.P302= | Silent (SNP) | VAF 69/399 reads (17%) | catalogued as rs377299313; called by muse, mutect2, varscan2
- ZNF831 | c.1044G>C p.S348= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs1555825939; called by muse, mutect2
- ZP2 | c.1938C>T p.A646= | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as COSV54811869; called by muse, mutect2, varscan2
- ZSCAN10 | c.402C>A p.A134= (on ENST00000252463; = p.A189= on NM_032805.3) | Silent (SNP) | VAF 55/151 reads (36%) | called by muse, mutect2, varscan2
- AC073316.1 | n.298G>T | RNA (SNP) | VAF 36/208 reads (17%) | called by muse, mutect2, varscan2
- AC074085.2 | n.329G>T | RNA (SNP) | VAF 62/412 reads (15%) | called by muse, mutect2, varscan2
- AC132807.2 | n.185G>A | RNA (SNP) | VAF 18/113 reads (16%) | catalogued as rs138639421; called by muse, mutect2, varscan2
- ACSF2 | c.128+521G>T | Intron (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- AL139327.1 | n.277T>C | RNA (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- ARFIP2 | chr11:6481449 G>T | 5'Flank (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- ARHGAP23P1 | chr16:33938542 A>T | 5'Flank (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916439 G>T | 5'Flank (SNP) | VAF 20/126 reads (16%) | catalogued as rs1199657474; called by muse, varscan2
- ARHGEF4 | chr2:130916456 C>G | 5'Flank (SNP) | VAF 18/142 reads (13%) | called by muse, varscan2
- ARMCX4 | c.1038+2516G>T | Intron (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100708339; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3692G>T | Intron (SNP) | VAF 50/135 reads (37%) | called by muse, mutect2, varscan2
- C4orf50 | c.-803G>T | 5'UTR (SNP) | VAF 21/222 reads (9%) | called by muse, mutect2
- CARD6 | chr5:40860064 G>T | 3'Flank (SNP) | VAF 22/160 reads (14%) | called by muse, mutect2, varscan2
- CCM2 | c.*92G>T | 3'UTR (SNP) | VAF 43/230 reads (19%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.275C>A | RNA (SNP) | VAF 135/412 reads (33%) | called by mutect2, varscan2
- CHCHD3 | c.170-10342G>T | Intron (SNP) | VAF 82/571 reads (14%) | called by muse, mutect2, varscan2
- CHN1 | c.*187T>A | 3'UTR (SNP) | VAF 65/244 reads (27%) | called by muse, mutect2, varscan2
- CNTN4 | c.56-39G>T | Intron (SNP) | VAF 52/348 reads (15%) | called by muse, varscan2
- CNTNAP3P2 | n.876C>G | RNA (SNP) | VAF 36/145 reads (25%) | called by muse, varscan2
- COL5A1 | c.654+7301G>T | Intron (SNP) | VAF 38/116 reads (33%) | called by muse, mutect2, varscan2
- DCDC1 | c.2715+8123G>T | Intron (SNP) | VAF 30/173 reads (17%) | called by muse, mutect2, varscan2
- DCHS2 | n.4987C>T | RNA (SNP) | VAF 31/251 reads (12%) | catalogued as COSV100602375; called by muse, mutect2, varscan2
- DCTN1 | c.3030-29A>T | Intron (SNP) | VAF 67/505 reads (13%) | called by muse, mutect2, varscan2
- DIP2C | c.2269-387A>T | Intron (SNP) | VAF 22/187 reads (12%) | called by muse, mutect2, varscan2
- DNM2 | c.1672-2534A>T | Intron (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- EDA | c.397-96153G>T | Intron (SNP) | VAF 23/84 reads (27%) | called by muse, varscan2
- EIPR1 | c.126+1277G>T | Intron (SNP) | VAF 15/218 reads (7%) | called by muse, mutect2
- EXOC7 | c.1929+76del | Intron (DEL) | VAF 76/485 reads (16%) | called by mutect2, pindel, varscan2
- FABP5P3 | chr7:152445572 C>A | 3'Flank (SNP) | VAF 52/353 reads (15%) | called by muse, mutect2, varscan2
- FAM27E5 | n.218A>T | RNA (SNP) | VAF 29/203 reads (14%) | called by muse, mutect2, varscan2
- FAM78B | c.263+11189C>T | Intron (SNP) | VAF 16/265 reads (6%) | called by muse, mutect2
- FBXW9 | chr19:12689136 C>A | 3'Flank (SNP) | VAF 44/256 reads (17%) | called by muse, mutect2, varscan2
- FOXI1 | c.*39A>G | 3'UTR (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- FRMPD2B | n.412C>G | RNA (SNP) | VAF 38/752 reads (5%) | catalogued as rs782441820; called by muse, mutect2
- GABBR1 | c.*10G>C | 3'UTR (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- GALNT13 | c.1396-970C>A | Intron (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2
- GP6 | c.*594A>C | 3'UTR (SNP) | VAF 75/596 reads (13%) | called by muse, mutect2, varscan2
- GUCY2EP | n.1275T>C | RNA (SNP) | VAF 23/167 reads (14%) | called by muse, mutect2, varscan2
- GUK1 | c.-186G>A | 5'UTR (SNP) | VAF 19/210 reads (9%) | called by muse, mutect2
- HMGA2 | c.249+43351A>G | Intron (SNP) | VAF 33/218 reads (15%) | catalogued as rs1336175150; called by muse, mutect2, varscan2
- HNRNPA1 | c.*113A>T | 3'UTR (SNP) | VAF 32/196 reads (16%) | called by muse, varscan2
- IGKV1-6 | c.-9G>T | 5'UTR (SNP) | VAF 53/443 reads (12%) | called by muse, mutect2, varscan2
- INPP4B | c.372+18823T>A | Intron (SNP) | VAF 28/189 reads (15%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1118+10C>A | Intron (SNP) | VAF 35/218 reads (16%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.361-35G>T | Intron (SNP) | VAF 15/205 reads (7%) | called by muse, mutect2
- LYPD3 | c.383-85C>A | Intron (SNP) | VAF 26/191 reads (14%) | called by muse, mutect2, varscan2
- LYPD3 | c.382+45G>T | Intron (SNP) | VAF 54/411 reads (13%) | catalogued as rs561074477; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85704C>G | Intron (SNP) | VAF 110/558 reads (20%) | called by muse, mutect2, varscan2
- MASP1 | c.1304-5675C>A | Intron (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2, varscan2
- MCC | c.2085+22G>A | Intron (SNP) | VAF 18/124 reads (15%) | called by muse, varscan2
- METTL26 | chr16:638165 G>T | 5'Flank (SNP) | VAF 59/454 reads (13%) | called by muse, mutect2, varscan2
- MGAM2 | c.5138-302G>T | Intron (SNP) | VAF 38/187 reads (20%) | catalogued as rs904149283; called by muse, mutect2, varscan2
- MTCL1 | c.3561+2462G>T | Intron (SNP) | VAF 56/288 reads (19%) | called by muse, varscan2
- MTHFSD | chr16:86555602 G>C | 5'Flank (SNP) | VAF 38/236 reads (16%) | called by muse, mutect2, varscan2
- MYL2 | c.354-26C>A | Intron (SNP) | VAF 114/638 reads (18%) | called by muse, mutect2, varscan2
- NCF2 | c.-89A>T | 5'UTR (SNP) | VAF 45/276 reads (16%) | called by muse, mutect2, varscan2
- NDUFAF5 | c.*130A>T | 3'UTR (SNP) | VAF 21/183 reads (11%) | called by muse, mutect2, varscan2
- NELL1 | c.1549+54957C>A | Intron (SNP) | VAF 70/387 reads (18%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.874G>A | RNA (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2, varscan2
- NPEPL1 | c.1001+104G>C | Intron (SNP) | VAF 43/251 reads (17%) | catalogued as COSV100622645; called by muse, mutect2, varscan2
- OLFML2A | c.670-440C>G | Intron (SNP) | VAF 77/249 reads (31%) | called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53167G>T | Intron (SNP) | VAF 24/167 reads (14%) | called by muse, mutect2, varscan2
- PEX11B | c.56+124G>T | Intron (SNP) | VAF 80/463 reads (17%) | called by muse, mutect2, varscan2
- PIEZO1 | c.161-1137G>T | Intron (SNP) | VAF 28/155 reads (18%) | catalogued as rs992614000; called by muse, mutect2, varscan2
- PKD2 | c.710-24C>A | Intron (SNP) | VAF 32/399 reads (8%) | called by muse, mutect2
- PRND | chr20:4732454 G>A | 3'Flank (SNP) | VAF 36/292 reads (12%) | called by muse, varscan2
- PSG5 | c.431-2817_431-2816del | Intron (DEL) | VAF 31/348 reads (9%) | called by pindel, varscan2
- RNA5-8SP2 | chr16:34158685 A>T | 5'Flank (SNP) | VAF 24/280 reads (9%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159027 G>T | 5'Flank (SNP) | VAF 30/177 reads (17%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159171 G>T | 5'Flank (SNP) | VAF 11/173 reads (6%) | called by muse, mutect2
- RPS28 | c.-29C>A | 5'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- SDF4 | c.715+29G>T | Intron (SNP) | VAF 31/187 reads (17%) | called by muse, mutect2, varscan2
- SLC35F1 | c.-4C>T | 5'UTR (SNP) | VAF 37/200 reads (19%) | called by muse, mutect2, varscan2
- SPAG9 | c.*1470C>G | 3'UTR (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- SRGAP3 | c.801+75G>T | Intron (SNP) | VAF 50/377 reads (13%) | called by muse, mutect2, varscan2
- SYT14 | c.*586A>T | 3'UTR (SNP) | VAF 100/382 reads (26%) | called by muse, mutect2, varscan2
- TMEM135 | c.*2774G>T | 3'UTR (SNP) | VAF 61/377 reads (16%) | called by muse, mutect2, varscan2
- TMEM51 | c.-267+10402G>T | Intron (SNP) | VAF 36/236 reads (15%) | called by muse, mutect2, varscan2
- TNFAIP2 | c.-663-742G>T | Intron (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- TNFRSF18 | c.*156G>T | 3'UTR (SNP) | VAF 6/45 reads (13%) | catalogued as COSV60776046; called by muse, mutect2, varscan2
- TPRX2P | n.289C>A | RNA (SNP) | VAF 38/225 reads (17%) | called by muse, mutect2, varscan2
- TUBB3 | c.277+14G>T | Intron (SNP) | VAF 68/420 reads (16%) | called by muse, mutect2, varscan2
- UBBP4 | n.819C>A | RNA (SNP) | VAF 102/712 reads (14%) | called by muse, varscan2
- UBN1 | chr16:4847219 C>G | 5'Flank (SNP) | VAF 24/368 reads (7%) | called by muse, mutect2
- VIPR2 | c.357+6895G>T | Intron (SNP) | VAF 10/64 reads (16%) | called by muse, varscan2
- XIST | n.10771C>A | RNA (SNP) | VAF 49/166 reads (30%) | called by muse, mutect2, varscan2
- ZNF222 | c.-118T>C | 5'UTR (SNP) | VAF 21/268 reads (8%) | called by muse, mutect2
- ZNF665 | c.-53-9134G>T | Intron (SNP) | VAF 16/154 reads (10%) | called by muse, varscan2
- ZNF99 | c.*342A>T | 3'UTR (SNP) | VAF 25/206 reads (12%) | called by muse, mutect2, varscan2
